TCGA case TCGA-GS-A9TT — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Testis; Tissue source site: Fundacio Clinic per a la Recerca Biomedica. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/33365d22-cb83-4d8e-a2d1-06b675f75f6e

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: Spain; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; ICD-10 code: C62.90; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Classification of tumor: primary; Age at diagnosis: 70.6 years (25,794 days); Year of diagnosis: 2011; AJCC staging edition: 7th; Ann Arbor clinical stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,163 days (3.2 years); Ann Arbor extranodal involvement: Yes; Sites of involvement: Lymph Node, Axillary / Lymph Node, Para-Aortic / Lymph Node, Splenic / Lymph Node, Supraclavicular / Bone, NOS / Testes.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: Yes; Greatest tumor dimension: 3 cm; Measurement unit: Centimeters.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Cyclophosphamide + Doxorubicin + Methotrexate + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP-21; Days to treatment start: 377 days (1.0 years); Days to treatment end: 482 days (1.3 years); Number of cycles: 6.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: Stem Cell Transplantation, NOS.

Follow-up (4 entries)
- Days to follow up: 844 days (2.3 years); Disease response: Tumor Free.
- Days to follow up: 1,163 days (3.2 years); Disease response: Tumor Free.
- Imaging type: PET; Imaging result: Negative; Timepoint: Within 2 Months After Completion of First-Course Treatment.
- ECOG performance status: 1.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Negative.
- CD10 (IHC): Negative.
- CD19 (Flow Cytometry): Positive.
- CD20 (IHC): Positive.
- CD22 (Flow Cytometry): Positive.
- CD23 (Flow Cytometry): Positive.
- CD5 (Flow Cytometry): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Positive.
- Immunoglobulin, Cytoplasmic (IHC): Positive.
- Immunoglobulin, Surface (IHC): Positive.
- Epstein-Barr Virus (IHC): Negative.
- Lactate Dehydrogenase 756 IU [Blood test normal range upper: 450].
- Involved Tissue, NOS epstein-barr virus (ISH): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85 kg; Height: 169 cm; BMI: 29.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-GS-A9TT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 130 mg.
  Slide TCGA-GS-A9TT-01A-01-TSA: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 30; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 10.
- Sample TCGA-GS-A9TT-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-GS-A9TT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal site involvement: 2; Bone marrow biopsy performed: Yes.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: Axillary; Lymph node involvement site: para-aortic; Lymph node involvement site: Splenic; Lymph node involvement site: supraclavicular.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Bone; Submitted tumor site: Testes.
- Tests performed: LDH level: 756; Mib 1 positive percent range: 76 - 100%; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD10 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunopheotypic analysis tested: MUM1 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunopheotypic analysis tested: BCL6 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunopheotypic analysis tested: CD23.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunopheotypic analysis tested: CD79a; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunopheotypic analysis tested: CD5.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunopheotypic analysis tested: CD19.
- Tests performed, Genetic testing results, Genetic testing result 10: Immunopheotypic analysis tested: CD22.
- Tests performed, Genetic testing results, Genetic testing result 11: Immunopheotypic analysis tested: Cytoplasmic Ig; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 12: Immunopheotypic analysis tested: Surface Ig; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 13: Immunopheotypic analysis tested: Eber; Immunophenotypic analysis method: Immunohistochemistry.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form, New tumor event: Treatment outcome at TCGA followup: Complete Remission/Response.
- Drug treatment 1: Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 2: Pharmaceutical therapy drug name: vincristina; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 3: Pharmaceutical therapy drug name: doxorubicina; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 4: Pharmaceutical therapy drug name: ciclofosfamida; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 5: Pharmaceutical therapy drug name: prednisona; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 6: Pharmaceutical therapy drug name: intrathecal methotrexate; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,163 days; disease-specific survival: no event (censored), 1,163 days; progression-free interval: no event (censored), 1,163 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-GS-A9TT-01A-11D-A381-01): tumor purity 0.91, ploidy 2.07, whole-genome doublings 0.
